Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A2CJ, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A2CJ-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Consultation Report

1CD-0-3
Carcinoma, papillary, follicular variant
8 340/3
Site: thyroid, nos c 73.9
4/18/11
for

Specimen(s) Received

1. Thyroid: left hemi thyroid stitch marks upper pole

Diagnosis

Multifocal papillary carcinoma, dominant 1.2 cm, follicular variant, left, and extensive follicular nodular disease: Thyroid, left hemithyroidectomy specimen

Synoptic Data

Clinical History:	No radiation exposure
Procedure:	Left hemithyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Left lobe:
	5.1 cm
	3.1 cm
	1.6 cm
	Isthmus +/- pyramidal lobe:
	1.6 cm
	0.6 cm
	0.6 cm
Specimen Weight:	14.68 g
Tumor Focality:	Multifocal, ipsilateral
----- DOMINANT TUMOR -----	
Tumor Laterality:	Left lobe *
Tumor Size:	Greatest dimension: 1.2cm
	Additional dimension: 1.0 cm
Histologic Type:	Papillary carcinoma, follicular variant *
	Follicular architecture *
	Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Totally encapsulated

[page 2 of 2]
Tumor Capsular Invasion:	Indeterminate
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
----- SECOND TUMOR -----	
Tumor Laterality:	Left lobe
Tumor Size:	Greatest dimension: 0.05cm
Histologic Type:	Papillary carcinoma, microcarcinoma (occult, small or microscopic) variant Follicular architecture Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	None
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT1b: Tumor more than 1 cm but not more than 2 cm in greatest dimension, limited to the thyroid
Regional Lymph Nodes (pN):	pNX: Regional lymph nodes cannot be assigned Number of regional lymph nodes examined: 0 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenomatoid nodule(s) or Nodular follicular disease

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically

verified by:

Gross Description

The specimen labeled with the patient's name and as "left hemithyroid stitch marks upper pole" consists of a left hemithyroidectomy specimen that is oriented with a suture and weighs 14.68 g. The lobe measures 5.1 cm SI x 3.1 cm ML x 1.6 cm AP and the isthmus measures 1.6 SI x 0.6 cm ML x 0.6 cm AP. The external surfaces have fibrous adhesions. No parathyroid glands or lymph nodes are identified grossly. The external surface is painted with blue dye. There are two well delineated nodules identified. The mid lobe contains a variegated red-tan nodule that measures 1.5 cm SI x 1.2 cm ML x 1.1 cm AP. The inferior pole contains a gelatinous nodule that measures 1.2 cm SI x 2.4 cm ML x 1.2 cm AP. The remainder of the thyroid tissue is grossly unremarkable. Sections of nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

1A-I lobe, superior to inferior
1J isthmus

Source: NCI Genomic Data Commons file d83484ba-a7f6-4bb4-882e-33b21bf6eab5 (TCGA-EM-A2CJ.09CC2B22-1C81-474B-82F2-D69FE5ACC413.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).